Somatic mutation profile of tumor specimen TCGA-HC-8256-01A (aliquot TCGA-HC-8256-01A-11D-2260-08) from TCGA case TCGA-HC-8256, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.7 years (19,598 days).
Specimen TCGA-HC-8256-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bc500b0-5f7e-48b2-998a-586cbe413e43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8256-10A (Blood Derived Normal), aliquot TCGA-HC-8256-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37873dbd-1853-48f6-9ce3-beadd1e82bed

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 12, Silent 10, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.2434T>A p.S812T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV53903043; called by muse, mutect2, varscan2
- ADGRV1 | c.2702T>C p.I901T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1373083030, COSV67982716; called by muse, mutect2, varscan2
- ATP13A5 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60867926, COSV60868012; called by muse, mutect2, varscan2
- ENPP3 | c.356G>A p.C119Y | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62953769; called by muse, mutect2, varscan2
- NEMF | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752834822, COSV53586969; called by muse, mutect2, varscan2
- PKD2 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1195484858, COSV52937453; called by muse, varscan2
- POLA1 | c.3937A>G p.I1313V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs756416451, COSV66885163; called by muse, mutect2, varscan2
- PRKCSH | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52950932, COSV99371963; called by muse, mutect2
- SHROOM3 | c.2144A>G p.H715R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56026591; called by muse, mutect2, varscan2
- SLITRK2 | c.2503G>T p.V835F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV59424388; called by muse, mutect2, varscan2
- THEMIS | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64070345, COSV64072144; called by muse, mutect2, varscan2
- ZNF571 | c.149G>C p.S50T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV60732814; called by muse, mutect2, varscan2
- DDX47 | c.1139_1156del p.H380_K385del | In Frame Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1104del p.F368Lfs*24 | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- ADAMDEC1 | c.567G>A p.V189= | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as COSV56474757; called by muse, mutect2, varscan2
- ASPA | c.27A>G p.E9= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV52152152; called by muse, varscan2
- CELSR1 | c.4254C>T p.C1418= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs370490684; called by muse, mutect2, varscan2
- GGNBP2 | c.750G>A p.L250= | Silent (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- HUNK | c.651G>A p.S217= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs763429549, COSV54226669; called by muse, mutect2, varscan2
- MYH1 | c.3381G>A p.E1127= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV56846212, COSV56847475; called by muse, mutect2
- PGLYRP2 | c.1191G>A p.P397= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV52992731; called by muse, mutect2
- PIK3CG | c.990G>T p.T330= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs564086584, COSV63247306, COSV63248850; called by muse, mutect2, varscan2
- PRSS27 | c.15G>A p.A5= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV57013168; called by muse, mutect2, varscan2
- XPR1 | c.783A>T p.T261= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV62555677; called by muse, varscan2
